Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AALG, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AALG-01A (Primary Tumor).

Concerning

Summary pathology report

Right orchidectomy; nonseminoma (MT 100%); diameter 6 cm; no angio-invasion; no invasion of rete testis; tumor confined to testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3

Teratoma, mature 908013
Site: B Testis NOS C62.9
9/3/14

Source: NCI Genomic Data Commons file fca06b48-067b-4d99-b534-9cbf4de8c7c7 (TCGA-2G-AALG.01A89705-3C15-4129-AA11-5D308504635B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).